Somatic mutation profile of tumor specimen BA2257D (aliquot aq-BA2257D) from BEATAML1.0 case 2249, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.5 years (15,169 days).
Specimen BA2257D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f49cb0c-566b-4e48-ba5f-511e4e36d965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2508D (Solid Tissue Normal), aliquot aq-BA2508D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31c3d188-61d7-4b0e-8cc4-2dadb513bd8b

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPEB3 | c.1607A>G p.D536G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV56461063; called by muse, mutect2, varscan2
- GJB2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs528216023, CM077564; ClinVar: uncertain significance; called by muse, mutect2
- INSYN2A | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs143897472; called by muse, mutect2, varscan2
- PID1 | c.233C>T p.T78M (on ENST00000354069 / NM_001330156.1; = p.T76M on NM_017933.5) | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.869); catalogued as rs775417884, COSV62472692; called by muse, mutect2, varscan2
- PTCHD1 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as rs761600819, COSV65061783; called by muse, mutect2, varscan2
- SCTR | c.695G>A p.W232* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as rs547605436; called by muse, varscan2
- TET2 | c.4990C>T p.Q1664* | Nonsense Mutation (SNP) | VAF 33/67 reads (49%) | catalogued as COSV54406376; called by muse, mutect2, varscan2
- BBOF1 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR156 | c.2183C>G p.P728R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- MAP3K1 | c.2747G>T p.C916F | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCDHB5 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPPL2B | c.1619C>G p.P540R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TET2 | c.2256_2259del p.N752Kfs*60 | Frame Shift Del (DEL) | VAF 147/329 reads (45%) | called by mutect2, varscan2
- ZNF365 | c.862C>A p.Q288K | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.053); called by muse, mutect2
- ABCC8 | c.2016C>T p.G672= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs771361396, COSV56846505; called by muse, mutect2, varscan2
- DMKN | c.333C>T p.H111= | Silent (SNP) | VAF 124/272 reads (46%) | catalogued as rs144163969; called by muse, mutect2, varscan2
- LTBP3 | c.2496C>T p.F832= | Silent (SNP) | VAF 71/170 reads (42%) | called by muse, mutect2, varscan2
- TMPRSS7 | c.1359C>T p.S453= (on ENST00000452346; = p.S327= on NM_001042575.2) | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as rs542321006; called by muse, mutect2, varscan2
- VPS52 | c.1299T>C p.Y433= | Silent (SNP) | VAF 115/250 reads (46%) | catalogued as rs1462542979; called by muse, mutect2, varscan2
- SEPTIN7P9 | n.400T>C | RNA (SNP) | VAF 52/176 reads (30%) | called by muse, varscan2
